Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RF, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RF-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinosarcoma / Mixed
Mullerian Tumor, malignant
8950/3
Site: Endometrium C54.1
JW 4/2/13

Specimens Submitted:

- 1: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPYNGO-OOPHORECTOMY:
- 2: OMENTUM; EXCISION:
- 3: LYMPH NODES, EXTERNAL ILIAC, RIGHT; BIOPSY:
- 4: LYMPH NODES, OBTURATOR, RIGHT; BIOPSY:
- 5: LYMPH NODES, HYPOGASTRIC, RIGHT; BIOPSY:
- 6: LYMPH NODES, COMMON ILIAC RIGHT; BIOPSY:
- 7: LYMPH NODES, EXTERNAL ILIAC, LEFT; BIOPSY:
- 8: LYMPH NODES, OBTURATOR, LEFT; BIOPSY:
- 9: LYMPH NODES, HYPOGASTRIC, LEFT; BIOPSY:
- 10: LYMPH NODES, COMMON ILIAC, LEFT; BIOPSY:
- 11: LYMPH NODES, PARA-AORTIC, LEFT; BIOPSY:
- 12: LYMPH NODES, PARA-AORTIC, RIGHT; BIOPSY:

DIAGNOSIS:

1. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPYNGO-OOPHORECTOMY::

Tumor Type:

Carcinosarcoma (Malignant mullerian mixed tumor) of endometrium with homologous differentiation

Myometrial Invasion:

(= < 50%)

Measures 5mm in maximum depth

Myometrium thickness measures 18mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Identified

Endometrium:

Residual endometrium is not identified

Myometrium:

Exhibits multiple leiomyomata

Adnexa:

Right and left ovaries exhibit endometriotic cysts. Right and left

** Continued on next page **

[page 2 of 3]
[REDACTED]

Fallopian tubes are benign, see note.

Comment: There is a focus of mild atypia identified in the left fallopian tube. An immunohistochemical stain shows no overexpression of p53.

2. OMENTUM; EXCISION:

- Benign fibroadipose tissue

3. LYMPH NODES, EXTERNAL ILIAC, RIGHT; BIOPSY::

Lymph Nodes:

Number of nodes examined:3

Number of metastatic nodes:0

4. LYMPH NODES, OBTURATOR, RIGHT; BIOPSY::

Lymph Nodes:

Number of nodes examined:8

Number of metastatic nodes:0

5. LYMPH NODES, HYPOGASTRIC, RIGHT; BIOPSY::

Lymph Nodes:

Benign fibroadipose tissue. No lymphoid tissue is identified in entirely submitted specimen.

6. LYMPH NODES, COMMON ILIAC RIGHT; BIOPSY::

Lymph Nodes:

Number of nodes examined:3

Number of metastatic nodes:0

7. LYMPH NODES, EXTERNAL ILIAC, LEFT; BIOPSY::

Lymph Nodes:

Number of nodes examined:2

Number of metastatic nodes:0

8. LYMPH NODES, OBTURATOR, LEFT; BIOPSY::

Lymph Nodes:

Number of nodes examined:3

Number of metastatic nodes:0

9. LYMPH NODES, HYPOGASTRIC, LEFT; BIOPSY::

Lymph Nodes:

Number of nodes examined:12

Number of metastatic nodes:0

** Continued on next page **

[page 3 of 3]
10. LYMPH NODES, COMMON ILIAC, LEFT; BIOPSY::

Lymph Nodes:

Number of nodes examined:1

Number of metastatic nodes:0

11. LYMPH NODES, PARA-AORTIC, LEFT; BIOPSY::

Lymph Nodes:

Number of nodes examined:3

Number of metastatic nodes:0

12. LYMPH NODES, PARA-AORTIC, RIGHT; BIOPSY::

Lymph Nodes:

Number of nodes examined:6

Number of metastatic nodes:0

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Source: NCI Genomic Data Commons file 6dc38eb8-c963-437e-864d-4fa6971f78ab (TCGA-N5-A4RF.A059F776-AF5B-4FF8-950C-2087D94395EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).